Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PJ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PJ-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

- "Stomach"

Adenocarcinoma:

Location: anterior wall of the gastric body

Borman's Classification

Histological pattern observed: tubular

Histologic grade

Lauren's classification

Measure of the greatest axis of the tumor: 10.5 cm

Ulceration: present

Involvement of:

Mucosa

Muscularis mucosae

Submucosa

Muscularis propria

Serous

Adjacent adipose tissue

Type of tumor invasion: spiculated

Inflammatory reaction: moderate

Tumor implantation in perivisceral adipose tissue: present

Proximal and distal margins: absence of neoplastic involvement.

Neural infiltration: not detected

Lymphatic vascular invasion: present

Blood vascular invasion: not detected

Lymph nodes:

Involved: 9

Capsular transposition: present

Conglomerated lymph nodes: not detected

Ratio of involved/dissected lymph nodes: 9/24

Not neoplastic stomach with chronic inflammation and complete intestinal metaplasia.

ICD O-3
Adenocarcinoma, tubular
8211/3
Site: Body stomach
C16.2
JW 3/7/14

Diagnostic discrepancy		
Case is (curable)		

Source: NCI Genomic Data Commons file 47536028-cd15-4bb8-a01e-68913d8d67bf (TCGA-VQ-A8PJ.D68770D3-4BFB-4A5A-BE70-410B2EE43FC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).